Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3367, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3367-01A (Primary Tumor).

[page 1 of 2]
TEST: Surgical Pathology

Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis:

Left renal mass

Post-Op Diagnosis:

Same

Clinical History:

Nothing dictated

Gross Description:

Received in a single container labeled "[REDACTED]" - left kidney and adrenal" is an 800 gram previously partially sectioned partially fragmented left nephrectomy specimen surrounded by a large amount of perinephric adipose tissue and faced anteriorly by Gerota's fascia. On reconstruction the specimen as received measures 26.2 x 11.6 x 8.9 cm. Within the superior antral medial aspect of the surrounding adipose tissue is a 7.2 x 5.0 x 1.6 cm grossly unremarkable adrenal gland. Within the hilar adipose tissue is a well defined 0.3 x 0.3 x 0.2 cm nodule of chalky appearing yellow orange tissue which may be consistent with adrenal rest. The nephrectomy specimen has as its margins of resection 1.9 cm of grossly patent renal artery, 0.5 cm of grossly patent renal vein, and 3.7 cm of grossly patent ureter. The capsule strips with slight difficulty to reveal an organ which on reconstruction measures 13.2 x 8.5 x 6.4 cm.

The cortex is granular and slightly lobulated red to brown with a 1.8 cm previously opened thin walled cystic structure with a smooth inner lining. A second cystic structure is noted on the anterior aspect of the lower pole measuring 1.8 cm. On sectioning this has a smooth inner lining and contains viscid gray brown mucoid fluid. Within the lower pole immediately adjacent to this cystic structure is a previously partially sectioned well circumscribed 4.9 x 4.4 x 3.9 cm nodular lesion with a focally hyalinized focally hemorrhagic gray pink to yellow cut surface. This grossly appears to extend beyond the plane of kidney but is well encapsulated without evidence of transection or infiltration into the surrounding adipose tissue. The lesion grossly appears to compress the surrounding parenchyma and focally appears to locally extend into vasculature. The remaining parenchyma has a cortex measuring up to 0.8 cm which is homogenous and red brown. The cortical medullary junction is well defined. The medulla is slight hyalinized tan gray to brown with sharp papillae. Calices and pelvis are lined by smooth gray white mucosa extending into the ureters.

Also received in the same container are three tissue cassettes each labeled "[REDACTED]". Representative sections are submitted labeled as follows: A - vascular and ureteral margins, B through E - representative lesion and surrounding tissue, F - random uninvolved parenchyma, G - representative adrenal gland, H - nodule from hilar adipose tissue.

Microscopic Description:

The slides are reviewed labeled [REDACTED]

Final Diagnosis:

Left kidney and adrenal:

Tumor characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type
2. Site: Lower pole left kidney
3. Size: 4.9 x 4.4 x 3.9 cm
4. Extent of tumor: Tumor limited to kidney and does not extend into perinephric tissues

Path Stage: T1b Nx Mx

[page 2 of 2]
5. Nuclear grade: Fuhrman grade 3/4
6. Lymphovascular space invasion: No.
7. Transcapsular invasion: No
8. Renal vein invasion: No
9. Vena caval invasion: Not resected
10. Adrenal gland: Adrenal cortical hyperplasia; no metastatic carcinoma identified

Surgical margin status:

1. Soft tissue margins: Negative
2. Ureteral margin: Negative
3. Vascular margin: Negative

Other significant findings:

1. Chronic pyelonephritis.
2. Glomerulosclerosis.
3. Benign retention cysts.
4. Nephrocalcinosis.
5. Hilar adrenal rest. PAS 9 SPC-A

Stage: pT1bNXMX

CPT: 88307 x 2

Comments

This test has been finalized at the [REDACTED] Campus.

#

Source: NCI Genomic Data Commons file 877ab798-744f-4181-bbd9-440bf31f7d36 (TCGA-A3-3367.2ADE205E-BE87-4112-935E-AB6AA69D81D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).